CCDI case PBBYXU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/ae31af18-aadb-43c3-b693-41778ddb4663

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 3.8 years (1,403 days).

Biospecimens (2 samples)
- Sample 0DLIF7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLIFN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
